Somatic mutation profile of tumor specimen MP2PRT-PASLUW-TMP1-A (aliquot MP2PRT-PASLUW-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASLUW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,467 days).
Specimen MP2PRT-PASLUW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60455503-c353-4adb-a3d3-4b715fac0067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLUW-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLUW-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3786c498-fa1a-442f-9a3c-3e291f63e1b7

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Intron 3, Nonsense Mutation 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 81/378 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.15292G>C p.E5098Q | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs768231571; called by muse, mutect2, varscan2
- ANKRA2 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs377503728; called by muse, mutect2, varscan2
- CR1 | c.830G>A p.R277H (on ENST00000367051; = p.R727H on NM_000573.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1295642971; called by mutect2, varscan2
- FAM227B | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs756019089; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 208/738 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by mutect2, varscan2
- GAD2 | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV52169442; called by muse, mutect2
- HOXD9 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 17/573 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99981629; called by muse, mutect2
- NRG2 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1051519654; called by muse, mutect2, varscan2
- OTUD6A | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 264/415 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as rs750198436, COSV100610887; called by muse, mutect2, varscan2
- SHPRH | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574465156, COSV51604046, COSV99261771; called by muse, mutect2, varscan2
- SLFN13 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99539814; called by muse, varscan2
- UHRF1BP1L | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV54437463; called by muse, mutect2, varscan2
- VANGL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 116/535 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs1313581338; called by muse, mutect2, varscan2
- ZNF729 | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62602299; called by muse, mutect2, varscan2
- ACOD1 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 153/479 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ADAMTS7 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BAHCC1 | c.6068_6070dup p.H2023_I2024insN | In Frame Ins (INS) | VAF 136/478 reads (28%) | called by mutect2, pindel, varscan2
- C2orf16 | c.2608C>G p.Q870E | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CCND3 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CHAMP1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 118/427 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DST | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- FLII | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 187/587 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPRASP2 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2
- HCN1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406834 TGCAACTTATTACTGTCTACAGGATTATACTACCCCATTCACAGTGTTAC>GGCCCA | Missense Mutation (DEL) | VAF 64/304 reads (21%) | called by pindel, varscan2*
- KCNJ3 | c.1403C>A p.A468D | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA6 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 24/641 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- PAPPA2 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 170/612 reads (28%) | called by muse, mutect2, varscan2
- PKIA | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PRKCQ | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 90/456 reads (20%) | called by muse, mutect2, varscan2
- RNFT2 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTL1 | c.3803C>A p.P1268Q | Missense Mutation (SNP) | VAF 162/708 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SAE1 | c.77_78insA p.W26* | Nonsense Mutation (INS) | VAF 166/604 reads (27%) | called by mutect2, pindel, varscan2
- SLFN13 | c.2116C>G p.Q706E | Missense Mutation (SNP) | VAF 118/463 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, varscan2
- SLFN13 | c.1594C>G p.P532A | Missense Mutation (SNP) | VAF 94/555 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TAOK1 | c.1951A>T p.M651L | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMCC1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TMPRSS6 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 128/406 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRPM6 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TSSK1B | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 157/600 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- WDR36 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- XKR6 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CPB1 | c.903G>C p.L301= | Silent (SNP) | VAF 128/463 reads (28%) | called by muse, mutect2, varscan2
- DAB1 | c.1137C>T p.L379= (on ENST00000371231; = p.L346= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 146/573 reads (25%) | called by muse, mutect2, varscan2
- KCNE4 | c.291C>T p.Y97= | Silent (SNP) | VAF 183/588 reads (31%) | catalogued as rs377154931; called by muse, mutect2, varscan2
- MTG2 | c.177G>A p.G59= | Silent (SNP) | VAF 100/398 reads (25%) | called by muse, mutect2
- NEK5 | c.525C>T p.I175= | Silent (SNP) | VAF 56/283 reads (20%) | called by muse, mutect2, varscan2
- OGFOD3 | c.717C>T p.F239= | Silent (SNP) | VAF 22/446 reads (5%) | catalogued as rs950740124; called by muse, mutect2
- PABPC4 | c.858G>A p.E286= | Silent (SNP) | VAF 123/428 reads (29%) | catalogued as COSV63293568; called by muse, mutect2, varscan2
- PCDH15 | c.4716T>C p.Y1572= (on ENST00000644397 / NM_001354429.2; = p.Y1514= on NM_001142771.2) | Silent (SNP) | VAF 224/544 reads (41%) | called by muse, varscan2
- SFRP1 | c.411C>T p.R137= | Silent (SNP) | VAF 134/544 reads (25%) | called by muse, mutect2, varscan2
- SPHK1 | c.1095C>T p.C365= (on ENST00000392496 / NM_001355139.2; = p.C379= on NM_021972.4) | Silent (SNP) | VAF 169/635 reads (27%) | catalogued as rs754010804, COSV60068792; called by muse, mutect2, varscan2
- SRGAP1 | c.939C>T p.S313= | Silent (SNP) | VAF 140/491 reads (29%) | catalogued as rs747601728, COSV61897533; called by muse, mutect2, varscan2
- TAF1C | c.1140C>T p.L380= | Silent (SNP) | VAF 129/488 reads (26%) | catalogued as rs200696785; called by muse, mutect2, varscan2
- TLR2 | c.1437C>G p.L479= | Silent (SNP) | VAF 111/326 reads (34%) | called by muse, mutect2, varscan2
- VSIG1 | c.864C>T p.S288= | Silent (SNP) | VAF 163/252 reads (65%) | catalogued as rs200336582, COSV54257600; called by muse, mutect2, varscan2
- ZC3H11B | c.783G>C p.V261= | Silent (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- ZCCHC4 | c.618G>A p.L206= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.97-1225C>G | Intron (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- DST | c.4296+4173C>T | Intron (SNP) | VAF 153/520 reads (29%) | catalogued as rs1221133763; called by muse, mutect2, varscan2
- SLC25A3 | c.282+195_282+196insCC | Intron (INS) | VAF 112/410 reads (27%) | called by mutect2, pindel, varscan2
